Surgical pathology report (de-identified scan), TCGA case TCGA-B9-A5W7, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site UNC, specimen TCGA-B9-A5W7-01A (Primary Tumor).

[page 1 of 4]
ICD-O-3
Carcinoma, papillary renal cell

8260/3

Site: R Kidney NOS
C64.9

gwo 3/18/13

Diagnosis:

A: Kidney, right, anterior renal mass, partial nephrectomy

Procedure: partial nephrectomy

Laterality: right

Histologic tumor type/subtype: papillary renal cell carcinoma

Sarcomatoid features: absent

Histologic grade (if applicable): 3

Tumor size (greatest dimension): 1.5 cm

Tumor focality: multifocal (see parts B and C)

Extent of tumor invasion (if present specify if macroscopic or microscopic):

Capsular invasion/perirenal adipose tissue: absent

Histologic assessment of surgical margins:

Renal parenchymal margin (partial nephrectomy only): positive

B: Kidney, right, posterior medial renal mass, partial nephrectomy

Procedure: partial nephrectomy

Laterality: right

Histologic tumor type/subtype: papillary

Sarcomatoid features: absent

Histologic grade (if applicable): grade 3

Tumor size (greatest dimension): 3.8 cm

Tumor focality: multifocal

[page 2 of 4]
Extent of tumor invasion (if present specify if macroscopic or microscopic):
Capsular invasion/perirenal adipose tissue: negative

Histologic assessment of surgical margins:
Renal parenchymal margin (partial nephrectomy only): negative

C: Kidney, right, posterior lateral renal mass, partial nephrectomy

Procedure: partial nephrectomy

Laterality: right

Histologic tumor type/subtype: papillary

Sarcomatoid features: absent

Histologic grade (if applicable): 3

Tumor size (greatest dimension): 2.5 cm

Tumor focality: multifocal

Extent of tumor invasion (if present specify if macroscopic or microscopic):
Capsular invasion/perirenal adipose tissue: negative

Histologic assessment of surgical margins:
Renal parenchymal margin (partial nephrectomy only): negative

AJCC Staging:

prT1a

pNx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

[page 3 of 4]
Clinical History:

-year-old male with right renal mass. Per , the patient has a history of renal cell carcinoma.

Gross Description:

Received are three appropriately labeled containers.

Container A is additionally labeled "kidney, right, anterior renal mass, partial nephrectomy" and consists of a 10.6 gram, 3.5 x 3.0 x 2.1 cm brown/tan fragment of kidney. The surgical margin is inked black. The renal capsule is inked yellow. A defect, 1.2 x 0.8 cm is identified and the external surface around the defect is inked yellow. The specimen is serially sectioned perpendicular to the blue and black inked tube margin. Sectioning reveals a pale tan, at least 1.5 x 1.2 x 1.0 cm well-circumscribed mass. The yellow inked defect goes right through this mass. The mass abuts the yellow-inked margin, black-inked margin and is less than 1 mm from the blue inked margin. The adjacent renal parenchyma is yellow to brown/tan, homogeneous.

Block Summary:

- A1 - Perpendicular sections of the first slice with blue inked margin, including closest approach of the mass
- A2-A3 - Representative sections of the mass with adjacent uninvolved renal parenchyma
- A4 - Additional representative section of the mass

Container B is additionally labeled "kidney, right, posterior medial renal mass, partial nephrectomy" and consists of a 28.0 gram, 4.0 x 3.7 x 3.0 cm fragment of kidney, that was received with a prior cut for tissue procurement. The capsule is inked blue and the surgical margin is inked black. Sectioning reveals a pale tan, friable, well-circumscribed mass, 3.8 x 3.6 x 2.9 cm. Focal gray to red/tan areas consistent with necrosis and hemorrhage respectively, are identified. Normal renal parenchyma is not identified in the specimen. The mass is 0.1 cm from the blue and black inked margins. Representative sections, including closest approach to the margin are submitted in blocks B1-B2.

Representative sections from the grossly necrotic and hemorrhagic area is submitted in block B3.

Container C is additionally labeled "kidney, right, posterior lateral renal mass" and consists of a 13.5 gram 3.4 x 2.7 x 2.2 cm fragment of kidney, with a 3.5 x 1.7 x 0.6 cm fibroadipose tissue attached. The capsule is inked blue and the resection

[page 4 of 4]
margin is inked black. The capsule is yellow to brown/tan, smooth, and unremarkable. Sectioning reveals a pale tan friable mass, 2.5 x 2.5 x 2.1 cm. The mass is hemorrhagic in the center, abuts the blue inked capsule and is 0.2 cm from the black inked resection margin.

Block Summary:

C1-C2 - Representative sections of the mass, depicting closest approach to the margins

C3 - Representative section of the mass with the attached fibroadipose tissue fragment

Pw T6A, this case will be permitted. The prior cancer was a different histology, treated with surgery only w/ 5-yr disease-free survival.

HPRAA Discrepancy		☒

Source: NCI Genomic Data Commons file 331f5224-6964-4a54-8137-335a926f8eec (TCGA-B9-A5W7.58D1FFA6-B836-4D7C-BF70-E6806526F195.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).